Somatic mutation profile of tumor specimen MP2PRT-PAVTRL-TMP1-A (aliquot MP2PRT-PAVTRL-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVTRL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,245 days).
Specimen MP2PRT-PAVTRL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01b4e1d1-8acb-4969-9f98-b669d2586f77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTRL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTRL-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/231aaa44-d679-4a2f-8330-c2774cc195a4

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 198/413 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BPIFB4 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 203/479 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs372134125; called by muse, mutect2, varscan2
- DOCK6 | c.3311G>A p.R1104Q | Missense Mutation (SNP) | VAF 231/573 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs570124917, COSV53917929; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAX5 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 162/183 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63905332; called by muse, mutect2, varscan2
- TTN | c.12835G>T p.A4279S (on ENST00000591111; = p.A4233S on NM_003319.4) | Missense Mutation (SNP) | VAF 83/428 reads (19%) | catalogued as rs1308710134; ClinVar: likely benign; called by muse, mutect2, varscan2
- IKZF1 | c.918_919insCTATTTCT p.K307Lfs*7 | Frame Shift Ins (INS) | VAF 154/380 reads (41%) | called by mutect2, varscan2
- SNCAIP | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 160/379 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TLR9 | c.1205_1206insGGGG p.F402Lfs*64 | Frame Shift Ins (INS) | VAF 138/336 reads (41%) | called by mutect2, varscan2
- USP34 | c.327_330del p.R109Sfs*13 | Frame Shift Del (DEL) | VAF 123/322 reads (38%) | called by mutect2, varscan2
- FAM3A | c.672G>A p.P224= | Silent (SNP) | VAF 215/231 reads (93%) | catalogued as rs782381702; called by muse, mutect2, varscan2
- JAG2 | c.3504G>A p.P1168= | Silent (SNP) | VAF 277/618 reads (45%) | catalogued as rs763479938; called by muse, mutect2, varscan2
- MSC | c.87G>T p.P29= | Silent (SNP) | VAF 224/503 reads (45%) | catalogued as COSV57696445; called by muse, mutect2, varscan2
- NAV3 | c.2565A>T p.R855= | Silent (SNP) | VAF 43/300 reads (14%) | catalogued as rs779905201; called by muse, mutect2, varscan2
- TIAM1 | c.4077C>T p.V1359= | Silent (SNP) | VAF 112/269 reads (42%) | catalogued as rs1319702898; called by muse, mutect2, varscan2
